Somatic mutation profile of tumor specimen TCGA-AA-3841-01A (aliquot TCGA-AA-3841-01A-01W-0900-09) from TCGA case TCGA-AA-3841, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 66.3 years (24,230 days).
Specimen TCGA-AA-3841-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9a97faf-4900-4483-ad51-804baa712478.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3841-10A (Blood Derived Normal), aliquot TCGA-AA-3841-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/827fe83f-c2f1-4a64-b925-8f6f8986ba4e

The open-access MAF lists 81 somatic variants for this specimen: 58 protein-altering or splice-affecting, 20 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 20, Frame Shift Ins 3, Nonsense Mutation 2, 3'UTR 1, In Frame Del 1, Frame Shift Del 1, Intron 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 103/171 reads (60%) | catalogued as rs775126020, CM980087, COSV57320525; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 10/25 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NAP1L3 | c.1505A>C p.K502T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV59073839, COSV59074072, COSV59075074; called by muse, mutect2, varscan2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 52/94 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM2A | c.739G>A p.G247S (on ENST00000219054; = p.G168S on NM_001308169.2) | Missense Mutation (SNP) | VAF 99/334 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1272316568, COSV99525225; called by muse, mutect2, varscan2
- ATRNL1 | c.2690C>T p.S897F | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as rs1554924632, COSV58101757; called by muse, mutect2, varscan2
- CADM1 | c.434G>A p.R145H | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs768807528, COSV59002182; called by muse, mutect2, varscan2
- CCDC88A | c.1856A>C p.H619P | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as COSV99710409; called by muse, mutect2, varscan2
- CCKBR | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 40/181 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202143110, COSV58098333; called by muse, mutect2, varscan2
- CLIP2 | c.2900C>T p.S967L | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs782670726, COSV99791558; called by muse, mutect2, varscan2
- CSMD3 | c.2530C>T p.R844W (on ENST00000297405 / NM_001363185.1; = p.R740W on NM_052900.3) | Missense Mutation (SNP) | VAF 57/222 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777713609, COSV52105465; called by muse, mutect2, varscan2
- DAP3 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58020316; called by muse, mutect2, varscan2
- ELMO1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1215535046, COSV60319959; called by muse, mutect2, varscan2
- ESRRG | c.1153G>T p.V385F | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.079); catalogued as COSV100752881; called by muse, mutect2, varscan2
- FOXP2 | c.1462T>A p.S488T | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.827); catalogued as COSV100646688; called by muse, mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 13/92 reads (14%) | catalogued as rs752538869; called by mutect2, varscan2
- FUT2 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV67178875; called by muse, mutect2, varscan2
- GCC2 | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as COSV100565438; called by muse, mutect2, varscan2
- GOLGA2 | c.1690G>A p.V564I | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.088); catalogued as rs1467927307, COSV57855293; called by muse, mutect2, varscan2
- HESX1 | c.112T>A p.L38I | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99907727; called by muse, mutect2, varscan2
- HYDIN | c.6739G>A p.A2247T | Missense Mutation (SNP) | VAF 57/239 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs372754655; called by muse, mutect2, varscan2
- ITGAX | c.706G>A p.V236M | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as rs375368829; called by muse, mutect2, varscan2
- KLHL41 | c.1296dup p.L433Tfs*9 | Frame Shift Ins (INS) | VAF 22/60 reads (37%) | catalogued as rs1288106608; called by mutect2, varscan2
- MAB21L1 | c.303G>T p.K101N | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100080093; called by muse, mutect2
- MAP3K1 | c.4315A>T p.I1439F | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV101266752; called by muse, mutect2, varscan2
- MS4A14 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 96/485 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as rs146613208; called by muse, mutect2, varscan2
- NCKAP1L | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 196/442 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV53207824; called by muse, mutect2, varscan2
- NPHS1 | c.3275G>A p.R1092H | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs144203682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OLFML2B | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1397019717, COSV54198735; called by muse, mutect2, varscan2
- OR10A3 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 87/352 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as rs777277922, COSV62459854; called by muse, mutect2, varscan2
- OR10Q1 | c.812C>A p.T271N | Missense Mutation (SNP) | VAF 146/333 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV100372195; called by muse, mutect2, varscan2
- OR11L1 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63315942; called by muse, mutect2, varscan2
- OR1J1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.053); catalogued as rs143862742, COSV99403151; called by muse, mutect2, varscan2
- OR5H15 | c.335G>T p.C112F | Missense Mutation (SNP) | VAF 66/386 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100736664; called by muse, mutect2, varscan2
- OTOA | c.595C>T p.R199W | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs148114778; called by muse, mutect2, varscan2
- PCDHA13 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.006); catalogued as COSV56525028; called by muse, mutect2, varscan2
- PCDHGC4 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 107/161 reads (66%) | SIFT tolerated (0.43); PolyPhen benign (0.184); catalogued as rs764874531, COSV52744520; called by muse, mutect2, varscan2
- PHYHIP | c.805G>A p.V269M | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.646); catalogued as rs756175019, COSV58687915; called by muse, mutect2, varscan2
- POTEE | c.2025A>C p.K675N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV58223193; called by muse, mutect2, varscan2
- PPARGC1A | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 119/195 reads (61%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1277352101, COSV99337889; called by muse, mutect2, varscan2
- PPIP5K2 | c.1421G>C p.G474A | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100383824, COSV100384014; called by muse, mutect2, varscan2
- PROX1 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54784100; called by muse, mutect2, varscan2
- PTPRB | c.803T>A p.L268H | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99717346; called by muse, mutect2, varscan2
- PZP | c.4075G>A p.D1359N | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs774255174, COSV54356689; called by muse, mutect2
- RASGRF2 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as COSV99429217; called by muse, mutect2, varscan2
- SASH3 | c.587T>G p.L196R | Missense Mutation (SNP) | VAF 249/279 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63555567; called by muse, mutect2, varscan2
- SERTAD2 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.085); catalogued as COSV57640896; called by muse, mutect2, varscan2
- SH2D4B | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs771907480, COSV57894022; called by muse, mutect2
- SLC13A5 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as rs146396085; ClinVar: uncertain significance; called by muse, mutect2
- STXBP5L | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV99872501; called by muse, mutect2, varscan2
- USP47 | c.4123G>A p.D1375N (on ENST00000399455 / NM_001372095.1; = p.D1287N on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100359545, COSV59694003; called by muse, mutect2, varscan2
- WDFY2 | c.486-1G>C p.X162_splice | Splice Site (SNP) | VAF 92/343 reads (27%) | catalogued as COSV53286749; called by muse, mutect2, varscan2
- ZC3H15 | c.563A>T p.E188V | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61921641; called by muse, mutect2, varscan2
- ZNF692 | c.953G>T p.R318I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100133832; called by muse, mutect2
- APC | c.4525_4526del p.L1509Efs*4 | Frame Shift Del (DEL) | VAF 82/156 reads (53%) | called by pindel, varscan2
- EPHB3 | c.2866dup p.L956Pfs*228 | Frame Shift Ins (INS) | VAF 20/78 reads (26%) | called by mutect2, pindel, varscan2
- GPR161 | c.316_318del p.L106del | In Frame Del (DEL) | VAF 92/209 reads (44%) | called by pindel, varscan2
- THBS2 | c.2920C>A p.Q974K | Missense Mutation (SNP) | VAF 2/9 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ANXA1 | c.138G>A p.S46= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs148187721, COSV99973931; called by muse, mutect2, varscan2
- DMD | c.3354A>G p.E1118= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as COSV63732544; called by muse, mutect2, varscan2
- GLMP | c.825C>T p.L275= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99827904; called by muse, mutect2
- GLP2R | c.1458C>T p.G486= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as rs139614327; called by muse, mutect2, varscan2
- GRIA1 | c.1275C>T p.N425= | Silent (SNP) | VAF 52/88 reads (59%) | catalogued as rs142814149; called by muse, mutect2, varscan2
- HACD2 | c.369T>C p.H123= | Silent (SNP) | VAF 34/144 reads (24%) | catalogued as rs374581565; called by muse, mutect2, varscan2
- HMGCLL1 | c.165C>A p.V55= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99232136; called by mutect2, varscan2
- KRT81 | c.873C>T p.A291= | Silent (SNP) | VAF 82/160 reads (51%) | catalogued as rs200239075; called by muse, mutect2, varscan2
- LHX9 | c.438C>T p.V146= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV100435877; called by muse, mutect2, varscan2
- MTRF1 | c.303A>G p.E101= | Silent (SNP) | VAF 70/503 reads (14%) | catalogued as COSV99520931; called by muse, mutect2
- PASK | c.327C>T p.S109= | Silent (SNP) | VAF 12/55 reads (22%) | called by muse, varscan2
- PCDHB10 | c.1341C>T p.N447= | Silent (SNP) | VAF 54/200 reads (27%) | catalogued as rs746631503, COSV53377853; called by muse, mutect2
- ROBO4 | c.696G>A p.T232= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs200292596, COSV60625851; called by muse, mutect2, varscan2
- SERPING1 | c.768C>T p.D256= | Silent (SNP) | VAF 144/732 reads (20%) | catalogued as rs146449093; called by muse, mutect2, varscan2
- SPEM2 | c.897T>C p.P299= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100424304; called by muse, mutect2, varscan2
- STAG1 | c.3042T>G p.L1014= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as COSV99365497; called by muse, mutect2, varscan2
- TDRD5 | c.543G>A p.A181= | Silent (SNP) | VAF 115/225 reads (51%) | catalogued as rs755225162, COSV54239012; called by muse, mutect2, varscan2
- TGIF2LY | c.363C>A p.I121= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV100339662; called by muse, mutect2, varscan2
- TMEM121B | c.1032C>A p.R344= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100083121; called by muse, mutect2, varscan2
- UPF2 | c.2289C>T p.T763= | Silent (SNP) | VAF 22/149 reads (15%) | catalogued as rs771530080, COSV62660149; called by muse, mutect2, varscan2
- FOLH1B | n.1573A>G | RNA (SNP) | VAF 15/131 reads (11%) | called by muse, mutect2, varscan2
- NRG1 | c.502+30946G>T | Intron (SNP) | VAF 10/106 reads (9%) | catalogued as COSV99827057, COSV99828419; called by muse, mutect2
- TXNIP | c.1176_*1dup | 3'UTR (INS) | VAF 57/218 reads (26%) | called by mutect2, pindel, varscan2
